CCDI case PBBVUY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/862fa448-46d1-4880-af6e-621230af12d1

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Alveolar soft part sarcoma: ICD-O-3 morphology code: 9581/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 16.5 years (6,026 days).

Biospecimens (3 samples)
- Sample 0DJXPE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJXPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJXRI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
